Somatic mutation profile of tumor specimen MP2PRT-PAVJWF-TMP1-A (aliquot MP2PRT-PAVJWF-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVJWF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,839 days).
Specimen MP2PRT-PAVJWF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3251b108-ad2b-499d-bb41-9c3754c6ab6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJWF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJWF-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/550101f9-0421-4911-9883-a18582fb49b9

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Ins 4, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.3835C>T p.R1279* | Nonsense Mutation (SNP) | VAF 41/425 reads (10%) | catalogued as rs863224886, CM162445, COSV65037841; ClinVar: likely pathogenic; called by muse, mutect2
- ASIC4 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 65/428 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.425); catalogued as COSV61731261; called by muse, mutect2, varscan2
- DENND1C | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs763139786; called by muse, mutect2
- DNAJC6 | c.1415G>C p.G472A | Missense Mutation (SNP) | VAF 67/381 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54780207; called by muse, mutect2, varscan2
- EHD2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 278/578 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV54406925; called by muse, varscan2
- FLT3 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 82/592 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
- KIAA0895 | c.1357C>T p.R453* (on ENST00000297063 / NM_001100425.2; = p.R402* on NM_015314.3) | Nonsense Mutation (SNP) | VAF 42/505 reads (8%) | catalogued as rs751552500; called by muse, mutect2
- MARK1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 75/405 reads (19%) | catalogued as rs1346347772, COSV65068250; called by muse, mutect2, varscan2
- PCDH19 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 301/682 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99720857; called by muse, mutect2, varscan2
- PEF1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 39/478 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as rs759567297, COSV65483721; called by muse, mutect2
- TTN | c.14998C>G p.Q5000E (on ENST00000591111; = p.Q4073E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/520 reads (10%) | PolyPhen benign (0.114); catalogued as rs1210762968; called by muse, mutect2
- GIGYF2 | c.2427dup p.E810Rfs*12 | Frame Shift Ins (INS) | VAF 61/376 reads (16%) | called by mutect2, pindel, varscan2
- KCND3 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 76/499 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MTMR3 | c.1891dup p.R631Pfs*56 | Frame Shift Ins (INS) | VAF 58/360 reads (16%) | called by mutect2, varscan2
- MTMR3 | c.1892delinsCC p.R631Pfs*56 | Frame Shift Ins (INS) | VAF 82/518 reads (16%) | called by mutect2*, pindel, varscan2*
- SSX5 | c.339dup p.E114Rfs*9 (on ENST00000347757 / NM_175723.1; = p.E155Rfs*9 on NM_021015.4) | Frame Shift Ins (INS) | VAF 70/208 reads (34%) | called by mutect2, pindel, varscan2
- TSPYL4 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 48/772 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ATP10A | c.1200C>T p.D400= | Silent (SNP) | VAF 93/466 reads (20%) | catalogued as rs542299949, COSV63518587; called by muse, mutect2, varscan2
- CRISPLD2 | c.252C>T p.D84= | Silent (SNP) | VAF 105/273 reads (38%) | catalogued as rs756263318; called by muse, mutect2, varscan2
- GSTA1 | c.216C>G p.L72= | Silent (SNP) | VAF 160/477 reads (34%) | called by muse, mutect2, varscan2
- RYR2 | c.12210G>A p.A4070= | Silent (SNP) | VAF 63/408 reads (15%) | catalogued as rs757703714, COSV100770553, COSV63685969, COSV63686121; called by muse, mutect2, varscan2
